Somatic mutation profile of cancer-model specimen HCM-CSHL-0730-C25-85A (3D Organoid, passage 4; aliquot HCM-CSHL-0730-C25-85A-01D-A82I-36), derived from the primary tumor of HCMI case HCM-CSHL-0730-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: GX; Age at diagnosis: 67.5 years (24,642 days).
Specimen HCM-CSHL-0730-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd3def47-2caf-4ccb-b204-7abd16042a93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0730-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0730-C25-10A-01D-A82I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f55ed8a-37ad-479b-841d-a2dc2d6db305

The open-access MAF lists 46 somatic variants for this specimen: 32 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 12, Frame Shift Ins 2, 5'UTR 1, Frame Shift Del 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 176/360 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 107/140 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912580, CM021284, COSV61684421, COSV61688134, COSV61692671; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 257/299 reads (86%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKRD33B | c.1457G>C p.R486P | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV56978715; called by muse, mutect2
- APOLD1 | c.398C>T p.T133I (on ENST00000326765 / NM_001130415.2; = p.T102I on NM_030817.3) | Missense Mutation (SNP) | VAF 301/708 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1284657175; called by muse, mutect2, varscan2
- DMRT3 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 159/201 reads (79%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.132); catalogued as rs566570084, COSV99505613; called by muse, mutect2, varscan2
- F13B | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 156/318 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.049); catalogued as rs766408940, COSV66373657; called by muse, mutect2, varscan2
- FRMD4B | c.2593G>A p.V865I | Missense Mutation (SNP) | VAF 190/426 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.138); catalogued as COSV101273378; called by muse, mutect2, varscan2
- GALNT18 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 15/539 reads (3%) | SIFT tolerated (1); PolyPhen probably damaging (0.953); catalogued as rs1430463379, COSV57153670; called by muse, mutect2
- GREM2 | c.249C>A p.S83R | Missense Mutation (SNP) | VAF 482/777 reads (62%) | SIFT tolerated (0.64); PolyPhen benign (0.018); catalogued as COSV58950057; called by muse, mutect2, varscan2
- HYDIN | c.7522C>T p.R2508C | Missense Mutation (SNP) | VAF 309/659 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs773554347, COSV99993984; called by muse, mutect2, varscan2
- KIT | c.884C>A p.T295N | Missense Mutation (SNP) | VAF 144/298 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.136); catalogued as COSV55398436; called by muse, mutect2, varscan2
- PCDHB13 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 27/1051 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as COSV53393614; called by muse, mutect2
- PTGES3L-AARSD1 | c.1541G>A p.R514H (on ENST00000421990 / NM_001136042.2; = p.R496H on NM_025267.3) | Missense Mutation (SNP) | VAF 166/383 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs748881742; called by muse, mutect2, varscan2
- SQSTM1 | c.75C>A p.F25L | Missense Mutation (SNP) | VAF 83/1345 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100657610; called by muse, mutect2
- TNC | c.6098G>A p.R2033H | Missense Mutation (SNP) | VAF 119/278 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs112853515, COSV60790736; called by muse, mutect2, varscan2
- TPSD1 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 205/455 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1401443140; called by muse, mutect2, varscan2
- ZNF513 | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 218/483 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs761846712, COSV52008153; called by muse, mutect2, varscan2
- ANAPC5 | c.60C>A p.H20Q | Missense Mutation (SNP) | VAF 244/562 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COLEC12 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 163/371 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD3 | c.8876T>A p.V2959E (on ENST00000297405 / NM_001363185.1; = p.V2790E on NM_052900.3) | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM214A | c.1253T>C p.V418A | Missense Mutation (SNP) | VAF 9/240 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.113); called by muse, mutect2
- HEPH | c.1858A>G p.M620V (on ENST00000343002; = p.M353V on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/295 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- HERC5 | c.1850_1851del p.V617Gfs*20 | Frame Shift Del (DEL) | VAF 56/171 reads (33%) | called by pindel, varscan2
- IRF2 | c.453_456dup p.D153Kfs*2 | Frame Shift Ins (INS) | VAF 54/189 reads (29%) | called by mutect2, varscan2
- NCOA7 | c.2569dup p.Y857Lfs*17 | Frame Shift Ins (INS) | VAF 178/269 reads (66%) | called by mutect2, pindel, varscan2
- OR9Q1 | c.102G>C p.M34I | Missense Mutation (SNP) | VAF 141/342 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLD3 | c.1335A>T p.K445N | Missense Mutation (SNP) | VAF 209/454 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RNF43 | c.2345C>G p.A782G | Missense Mutation (SNP) | VAF 35/531 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.501); called by muse, mutect2
- SPTAN1 | c.7108G>A p.E2370K | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.207); called by muse, mutect2
- SYTL4 | c.1773T>A p.D591E | Missense Mutation (SNP) | VAF 229/544 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- TLR8 | c.1858C>T p.L620F (on ENST00000218032 / NM_138636.5; = p.L638F on NM_016610.4) | Missense Mutation (SNP) | VAF 72/232 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- AKAP17A | c.321C>T p.S107= | Silent (SNP) | VAF 342/833 reads (41%) | catalogued as rs773634719; called by muse, mutect2, varscan2
- C4BPA | c.1113T>C p.N371= | Silent (SNP) | VAF 214/340 reads (63%) | called by muse, mutect2, varscan2
- CNNM4 | c.1659C>T p.A553= | Silent (SNP) | VAF 54/360 reads (15%) | catalogued as rs763026644, COSV65662028; called by muse, mutect2, varscan2
- DDB1 | c.1881G>A p.K627= | Silent (SNP) | VAF 36/384 reads (9%) | catalogued as COSV57103908; called by muse, mutect2
- DNAH2 | c.10677G>A p.L3559= | Silent (SNP) | VAF 21/171 reads (12%) | called by muse, mutect2, varscan2
- FGF21 | c.567C>T p.G189= | Silent (SNP) | VAF 192/514 reads (37%) | called by mutect2, varscan2
- HDX | c.1272G>A p.V424= | Silent (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2, varscan2
- OR10V1 | c.582C>T p.R194= | Silent (SNP) | VAF 209/462 reads (45%) | catalogued as rs377363304, COSV100275759; called by muse, mutect2, varscan2
- PACSIN2 | c.162G>A p.A54= | Silent (SNP) | VAF 128/596 reads (21%) | catalogued as rs201219931, COSV54321316, COSV99605943; called by muse, mutect2, varscan2
- SERPINA1 | c.1005C>A p.V335= | Silent (SNP) | VAF 269/695 reads (39%) | called by muse, mutect2, varscan2
- SPCS3 | c.447C>T p.N149= | Silent (SNP) | VAF 111/270 reads (41%) | catalogued as rs1337273662, COSV101543716; called by muse, mutect2, varscan2
- TRNAU1AP | c.600C>T p.Y200= | Silent (SNP) | VAF 252/293 reads (86%) | called by muse, mutect2, varscan2
- PNRC2 | c.-79C>T | 5'UTR (SNP) | VAF 242/289 reads (84%) | called by muse, mutect2, varscan2
- TMEM191C | c.296+37G>C | Intron (SNP) | VAF 120/274 reads (44%) | called by muse, mutect2, varscan2
